MMRF case MMRF_1466 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e182d48d-158e-4c22-bad8-35f39b087dd8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.6 years (25,798 days); ISS stage: III; Days to last known disease status: 1,355 days (3.7 years); Days to last follow up: 1,355 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 88 days; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 115 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 745 days (2.0 years); Days to treatment end: 943 days (2.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 745 days (2.0 years); Days to treatment end: 942 days (2.6 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,327 days (3.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.588 mg/dL; Immunoglobulin G 50.8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 9.6 g/dL; Glucose 5.67 mmol/L.
- Day 88 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 9.87 g/L; Immunoglobulin A 1.19 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.16 µg/mL; Lactate Dehydrogenase 8.35 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.58 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.49 mmol/L.
- Day 179 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 7.04 mmol/L.
- Day 254 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.58 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 6.77 mmol/L.
- Day 305 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 7.04 mmol/L.
- Day 394 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.37 mmol/L.
- Day 576 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 8.75 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 112 ×10⁹/L.
- Day 667 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 3.04 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 6.71 mmol/L.
- Day 744 (ECOG 1): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 8.03 mmol/L.
- Day 800 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 6.49 mmol/L.
- Day 890 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.15 mg/dL; Immunoglobulin G 6.45 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 6.6 mmol/L.
- Day 989 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 1,065 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 2.22 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 7.65 mmol/L.
- Day 1,178 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 8.82 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.33 mmol/L.
- Day 1,241 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 6.71 mmol/L.
- Day 1,355 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 7.15 mmol/L.

Other clinical attributes
- Day -3: Weight: 94 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Multiple Myeloma.

Biospecimens (3 samples)
- Sample MMRF_1466_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1466_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
- Sample MMRF_1466_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 744 days (2.0 years).
